Somatic mutation profile of tumor specimen TCGA-BC-A10Z-01A (aliquot TCGA-BC-A10Z-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10Z, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,913 days).
Specimen TCGA-BC-A10Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32e6a3a2-930c-4efa-9eec-9239e53bc2ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10Z-11A (Solid Tissue Normal), aliquot TCGA-BC-A10Z-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87a9dfcd-4fe3-4de9-bfde-b7dfa561a947

The open-access MAF lists 191 somatic variants for this specimen: 149 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 39, Frame Shift Del 13, Nonsense Mutation 10, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Splice Site 1, RNA 1, Splice Region 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKH | c.1124_1126del p.S375del | In Frame Del (DEL) | VAF 37/135 reads (27%) | catalogued as rs121908406; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA1 | c.2828T>C p.M943T | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV66066695; called by muse, mutect2, varscan2
- ACACB | c.2767G>C p.A923P | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622195; called by muse, mutect2, varscan2
- ACACB | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622197; called by muse, mutect2, varscan2
- ACOT2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53150439; called by muse, mutect2, varscan2
- ACP1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55243370; called by muse, mutect2
- ACTN1 | c.1548G>T p.K516N | Missense Mutation (SNP) | VAF 108/119 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51992198; called by muse, mutect2
- ACTN1 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 107/119 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV51992225; called by muse, mutect2
- ADGRL4 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 177/359 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.243); catalogued as COSV66061793; called by muse, mutect2, varscan2
- AMHR2 | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57685816; called by muse, mutect2, varscan2
- ANO4 | c.1978T>A p.W660R (on ENST00000392977 / NM_001286615.2; = p.W625R on NM_178826.4) | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54596608; called by muse, mutect2, varscan2
- APC | c.5753T>C p.I1918T | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57345914; called by muse, mutect2, varscan2
- AR | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV65957346; called by muse, mutect2, varscan2
- ARHGEF10L | c.2988A>C p.E996D | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51432851; called by muse, mutect2, varscan2
- ARSG | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 224/699 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.695); catalogued as COSV71593207; called by muse, mutect2, varscan2
- BAG4 | c.1330A>C p.K444Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54860238; called by muse, mutect2, varscan2
- BMP1 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100108922; called by muse, mutect2, varscan2
- BTBD1 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 161/315 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV55603088; called by muse, mutect2, varscan2
- C4orf45 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101465063; called by muse, mutect2
- C4orf45 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.99); catalogued as COSV101465064; called by muse, mutect2
- CABIN1 | c.2687A>T p.H896L | Missense Mutation (SNP) | VAF 135/270 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54082087; called by muse, mutect2, varscan2
- CACNA1S | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 367/588 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs773440873, COSV62939779; called by muse, mutect2, varscan2
- CALR | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 174/339 reads (51%) | catalogued as COSV57117629, COSV57135735; called by muse, mutect2, varscan2
- CARD11 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 164/335 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.658); catalogued as COSV67799352; called by muse, mutect2, varscan2
- CCBE1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV71670845; called by muse, mutect2, varscan2
- CCDC102A | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV50776618; called by muse, mutect2, varscan2
- CCDC59 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1251732500, COSV50259180; called by muse, mutect2, varscan2
- CDIPT | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54888995; called by muse, mutect2, varscan2
- CENPE | c.2951A>T p.K984I | Missense Mutation (SNP) | VAF 69/80 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54379305, COSV54381514; called by muse, mutect2, varscan2
- CHRM2 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57772920; called by muse, mutect2, varscan2
- CHSY1 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs1042167798, COSV54253430; called by muse, mutect2, varscan2
- CLEC14A | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100643473; called by muse, mutect2, varscan2
- CNKSR2 | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54256710; called by muse, mutect2, varscan2
- CPNE7 | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV52012944, COSV52013696; called by muse, mutect2, varscan2
- CR1 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 226/495 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65458402; called by muse, mutect2, varscan2
- CSMD3 | c.4809C>A p.N1603K (on ENST00000297405 / NM_001363185.1; = p.N1499K on NM_052900.3) | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52187080, COSV99844010; called by muse, mutect2, varscan2
- DEFA4 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.529); catalogued as COSV52404802; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV50051634; called by muse, mutect2, varscan2
- DUSP6 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV54378666; called by muse, mutect2, varscan2
- DYNC1H1 | c.6653A>T p.H2218L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64137193; called by muse, mutect2, varscan2
- EFCAB5 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 107/197 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV57930335; called by muse, mutect2, varscan2
- EHBP1 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771286650, COSV50420678; called by muse, mutect2, varscan2
- ELAVL1 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60966657; called by muse, mutect2, varscan2
- EPC2 | c.802G>T p.V268F | Missense Mutation (SNP) | VAF 131/319 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV51544096; called by muse, mutect2, varscan2
- EPHA6 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.988); catalogued as COSV67572956; called by muse, mutect2, varscan2
- FAM102B | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64239990; called by muse, mutect2, varscan2
- FBN1 | c.2090A>C p.Q697P | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as CM148672, COSV57317437; called by muse, mutect2, varscan2
- FBXO47 | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 152/253 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65241821; called by muse, mutect2, varscan2
- FDX2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV53345694; called by muse, mutect2, varscan2
- FREM1 | c.2579A>G p.D860G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967367549, COSV66524027; called by muse, mutect2, varscan2
- GABRG1 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 158/390 reads (41%) | catalogued as COSV54954480, COSV54960971, COSV99777223; called by muse, varscan2
- GABRG1 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV54957180, COSV99777259; called by muse, varscan2
- GADL1 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 114/265 reads (43%) | catalogued as rs767147995, COSV56978948, COSV56978993; called by muse, mutect2, varscan2
- GALNT17 | c.1163G>T p.S388I | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as COSV61163320; called by muse, varscan2
- GSDMD | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52797265; called by muse, mutect2, varscan2
- HID1 | c.2033G>A p.W678* | Nonsense Mutation (SNP) | VAF 75/229 reads (33%) | catalogued as COSV59351564; called by muse, mutect2, varscan2
- HK1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV53858603; called by muse, mutect2, varscan2
- HMGCS1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57290251; called by muse, mutect2, varscan2
- HOXC10 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV57726324; called by muse, mutect2, varscan2
- ICE2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV55031580; called by muse, mutect2, varscan2
- IGLON5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as rs1478891688, COSV54536011; called by muse, mutect2, varscan2
- ITPRID1 | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV60075223; called by muse, mutect2, varscan2
- JPH4 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV58112822; called by muse, mutect2, varscan2
- KIF9 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1395331540, COSV55519709; called by muse, mutect2, varscan2
- KRT34 | c.1242C>A p.C414* | Nonsense Mutation (SNP) | VAF 56/158 reads (35%) | catalogued as rs138365209, COSV67449880; called by muse, mutect2, varscan2
- KRT6B | c.1426C>T p.L476= | Splice Region (SNP) | VAF 83/191 reads (43%) | catalogued as COSV52883869; called by muse, mutect2, varscan2
- KRT75 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.464); catalogued as COSV52872973; called by muse, mutect2, varscan2
- LNPEP | c.1410G>T p.W470C | Missense Mutation (SNP) | VAF 170/320 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51478195; called by muse, mutect2, varscan2
- LRP1B | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 162/358 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV67222659; called by muse, mutect2, varscan2
- LRP4 | c.3959G>A p.C1320Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891590824, COSV66135961; called by muse, mutect2, varscan2
- LRRIQ1 | c.4397C>A p.S1466* | Nonsense Mutation (SNP) | VAF 92/197 reads (47%) | catalogued as COSV67831149; called by muse, mutect2, varscan2
- MGAM | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074702; called by muse, mutect2, varscan2
- MXRA8 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58510633; called by muse, mutect2, varscan2
- MYC | c.493G>A p.A165T (on ENST00000377970; = p.A180T on NM_002467.6) | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV52373016, COSV52375967; called by muse, mutect2, varscan2
- MYO18B | c.7492C>T p.P2498S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59135119; called by muse, mutect2, varscan2
- MYT1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60506225; called by muse, mutect2, varscan2
- NAA25 | c.1242T>A p.H414Q | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55704418; called by muse, mutect2, varscan2
- NAV3 | c.3226T>G p.S1076A | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV57081331, COSV57095258; called by muse, mutect2, varscan2
- NCOR1 | c.4491del p.M1498* | Frame Shift Del (DEL) | VAF 60/132 reads (45%) | catalogued as COSV51975512; called by pindel, varscan2*
- NGEF | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.712); catalogued as rs1436671055, COSV50922547; called by muse, mutect2, varscan2
- NOD2 | c.998G>C p.C333S | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56051015; called by mutect2, varscan2
- OR1L8 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV59186482; called by muse, mutect2, varscan2
- OR4A5 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 175/395 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as COSV60522640; called by muse, mutect2, varscan2
- OR51V1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58315115; called by muse, mutect2, varscan2
- OR5B17 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.919); catalogued as COSV62160298, COSV62160338; called by muse, mutect2, varscan2
- PCM1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61516385; called by muse, mutect2, varscan2
- PDS5A | c.348A>G p.I116M | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57826074; called by muse, mutect2, varscan2
- PITPNM2 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54901155; called by muse, mutect2, varscan2
- PLXNA4 | c.5294G>A p.S1765N | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs1326870251, COSV58128292; called by muse, mutect2, varscan2
- POLQ | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 208/457 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV51752409; called by muse, mutect2, varscan2
- POSTN | c.419A>T p.E140V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65713043; called by muse, mutect2, varscan2
- POU2F2 | c.4G>T p.V2F | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV60762943; called by muse, mutect2, varscan2
- POU5F2 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67937689; called by muse, mutect2, varscan2
- PRAG1 | c.2561C>A p.T854N | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as COSV58161291; called by muse, mutect2, varscan2
- PRR16 | c.890G>T p.R297M (on ENST00000407149 / NM_001300783.2; = p.R274M on NM_016644.2) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101086118; called by muse, mutect2, varscan2
- PRR16 | c.891G>T p.R297S (on ENST00000407149 / NM_001300783.2; = p.R274S on NM_016644.2) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101086120, COSV65394765; called by muse, mutect2, varscan2
- PSD2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs146689892; called by muse, mutect2, varscan2
- PTPN3 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs376647767, COSV99356039; called by muse, mutect2, varscan2
- RACK1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs768541673, COSV59319228; called by muse, mutect2, varscan2
- RFX6 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV60585161; called by muse, mutect2, varscan2
- RNF145 | c.496G>T p.E166* (on ENST00000424310 / NM_001199383.2; = p.E194* on NM_144726.2) | Nonsense Mutation (SNP) | VAF 274/554 reads (49%) | catalogued as COSV50866664; called by muse, varscan2
- RNF145 | c.495G>T p.L165F (on ENST00000424310 / NM_001199383.2; = p.L193F on NM_144726.2) | Missense Mutation (SNP) | VAF 274/552 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV50866691; called by muse, varscan2
- SDS | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57453595; called by muse, mutect2, varscan2
- SIGLEC8 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 46/96 reads (48%) | PolyPhen benign (0.336); catalogued as COSV58473951; called by muse, mutect2, varscan2
- SLC16A9 | c.909C>A p.N303K | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV68098495, COSV68098962; called by mutect2, varscan2
- SLC4A1 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV52260247; called by muse, mutect2, varscan2
- SLC6A2 | c.1842G>T p.W614C | Missense Mutation (SNP) | VAF 133/141 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV54916698; called by muse, mutect2, varscan2
- SLCO6A1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 154/337 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV65810139; called by muse, mutect2, varscan2
- SMTN | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60778404; called by muse, mutect2, varscan2
- SP110 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV51252082; called by muse, mutect2, varscan2
- SPATA5L1 | c.2117A>G p.E706G | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV59744712; called by muse, mutect2, varscan2
- STAC | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.924); catalogued as COSV56211107; called by muse, varscan2
- TEX19 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61017058, COSV61017269; called by muse, mutect2, varscan2
- THADA | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 232/428 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67090163; called by muse, mutect2, varscan2
- TIMM44 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV54491869; called by muse, mutect2, varscan2
- TLE6 | c.1019G>A p.C340Y (on ENST00000246112 / NM_001143986.2; = p.C217Y on NM_024760.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55735770; called by muse, mutect2, varscan2
- TLN1 | c.7577G>A p.R2526Q | Missense Mutation (SNP) | VAF 168/489 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1314310484, COSV59207653; called by muse, mutect2, varscan2
- TMEM132E | c.1309C>T p.P437S (on ENST00000321639; = p.P527S on NM_001304438.2) | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs760312005, COSV58695324; called by muse, mutect2, varscan2
- TRIM3 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV61984038; called by muse, mutect2, varscan2
- TTC39A | c.1213G>T p.D405Y (on ENST00000447632 / NM_001297665.1; = p.D370Y on NM_001080494.3) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV52958277; called by muse, mutect2, varscan2
- TTN | c.52136T>A p.V17379E (on ENST00000591111; = p.V9955E on NM_003319.4) | Missense Mutation (SNP) | VAF 143/347 reads (41%) | PolyPhen possibly damaging (0.558); catalogued as COSV60081053; called by muse, mutect2, varscan2
- TTN | c.48949G>A p.D16317N (on ENST00000591111; = p.D8893N on NM_003319.4) | Missense Mutation (SNP) | VAF 83/168 reads (49%) | PolyPhen probably damaging (0.998); catalogued as COSV60081105; called by muse, mutect2, varscan2
- TYR | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as HM070075, COSV54474922; called by muse, mutect2, varscan2
- WDR41 | c.78A>T p.E26D | Missense Mutation (SNP) | VAF 149/309 reads (48%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV56998890; called by muse, mutect2, varscan2
- XPO5 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 146/241 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54830314; called by muse, mutect2, varscan2
- ZFYVE26 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs759231803, COSV61328760; called by muse, mutect2, varscan2
- ZKSCAN1 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as COSV60874115; called by muse, mutect2, varscan2
- ZNF106 | c.3587C>T p.S1196L | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs760102454, COSV55516901; called by muse, mutect2, varscan2
- ZNF285 | c.1556A>C p.K519T | Missense Mutation (SNP) | VAF 191/387 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58409110; called by muse, mutect2, varscan2
- ZNF429 | c.1837A>T p.K613* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | catalogued as COSV61916240; called by muse, mutect2, varscan2
- ZNF486 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV58719261; called by muse, mutect2, varscan2
- ADAM12 | c.2561del p.P854Lfs*85 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | called by mutect2, pindel, varscan2
- AP3M2 | c.613dup p.V205Gfs*3 | Frame Shift Ins (INS) | VAF 119/307 reads (39%) | called by mutect2, pindel, varscan2
- APOB | c.11583_11598del p.I3862Lfs*17 | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | called by mutect2, pindel, varscan2
- C8orf31 | n.538+1G>A | Splice Site (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- CHD9 | c.7618_7625dup p.H2542Qfs*12 (on ENST00000398510 / NM_001382353.1; = p.H2526Qfs*12 on NM_025134.7) | Frame Shift Ins (INS) | VAF 90/102 reads (88%) | called by mutect2, pindel*, varscan2
- IYD | c.374_383del p.T125Mfs*13 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- KCNU1 | c.1201_1210del p.R402Wfs*8 | Frame Shift Del (DEL) | VAF 178/426 reads (42%) | called by mutect2, pindel, varscan2
- KIF19 | c.1168del p.Q390Rfs*285 | Frame Shift Del (DEL) | VAF 66/133 reads (50%) | called by mutect2, pindel, varscan2
- LYZL6 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MUC16 | c.35778_35781del p.T11927Qfs*16 | Frame Shift Del (DEL) | VAF 90/228 reads (39%) | called by mutect2, pindel, varscan2
- NHS | c.843del p.L283* | Frame Shift Del (DEL) | VAF 73/185 reads (39%) | called by mutect2, pindel, varscan2
- NLGN1 | c.782del p.G261Vfs*10 | Frame Shift Del (DEL) | VAF 82/274 reads (30%) | called by mutect2, pindel*, varscan2
- PRAMEF20 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 152/313 reads (49%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SPINK5 | c.2576del p.G859Efs*65 | Frame Shift Del (DEL) | VAF 78/176 reads (44%) | called by mutect2, pindel, varscan2
- SPIRE1 | c.1786del p.C596Vfs*58 (on ENST00000409402 / NM_001128626.2; = p.C582Vfs*58 on NM_020148.3) | Frame Shift Del (DEL) | VAF 20/220 reads (9%) | called by mutect2, pindel
- SYNRG | c.3730G>C p.E1244Q | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TIAL1 | c.666del p.R222Sfs*13 | Frame Shift Del (DEL) | VAF 58/159 reads (36%) | called by mutect2, pindel, varscan2
- ZNF835 | c.301del p.E101Rfs*53 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- ABCA2 | c.6510C>T p.F2170= (on ENST00000614293; = p.F2140= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs748279912, COSV55801752; called by muse, mutect2, varscan2
- ACTN2 | c.207C>A p.G69= | Silent (SNP) | VAF 143/317 reads (45%) | catalogued as COSV63975128; called by muse, mutect2, varscan2
- ANKRD46 | c.372C>T p.V124= | Silent (SNP) | VAF 102/247 reads (41%) | catalogued as COSV59513796, COSV59514545; called by muse, mutect2, varscan2
- BCL11B | c.2460C>G p.G820= (on ENST00000357195 / NM_001282237.2; = p.G749= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV61735707; called by muse, mutect2, varscan2
- CHL1 | c.2232C>G p.G744= (on ENST00000397491 / NM_001253387.1; = p.G760= on NM_006614.4) | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV56593991; called by muse, mutect2, varscan2
- CLEC14A | c.864C>T p.T288= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100643472; called by muse, mutect2, varscan2
- CSPP1 | c.3471T>G p.G1157= (on ENST00000676605; = p.G1116= on NM_024790.6) | Silent (SNP) | VAF 91/194 reads (47%) | catalogued as COSV51584829; called by muse, mutect2, varscan2
- CYP26B1 | c.426C>T p.R142= | Silent (SNP) | VAF 70/166 reads (42%) | catalogued as COSV50011896; called by muse, varscan2
- DLG3 | c.633A>G p.R211= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs750963382, COSV52082676; called by muse, mutect2, varscan2
- DOT1L | c.2508G>A p.G836= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV67109869; called by muse, mutect2, varscan2
- DSCAM | c.3552C>A p.T1184= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as COSV68027105; called by muse, mutect2, varscan2
- EBF2 | c.1392C>T p.S464= | Silent (SNP) | VAF 170/357 reads (48%) | catalogued as rs151033193; called by muse, mutect2, varscan2
- EPHA4 | c.1152C>A p.V384= | Silent (SNP) | VAF 121/266 reads (45%) | catalogued as COSV56033736; called by muse, mutect2, varscan2
- FAH | c.756G>A p.G252= | Silent (SNP) | VAF 95/199 reads (48%) | catalogued as rs202041382; called by muse, mutect2, varscan2
- GLB1 | c.600G>A p.L200= | Silent (SNP) | VAF 86/205 reads (42%) | catalogued as COSV56563930; called by muse, mutect2, varscan2
- GPR141 | c.408T>C p.S136= | Silent (SNP) | VAF 94/227 reads (41%) | catalogued as COSV57732386; called by muse, mutect2, varscan2
- INPP5D | c.2988G>A p.L996= (on ENST00000445964 / NM_001017915.3; = p.L995= on NM_005541.5) | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV64037216; called by muse, mutect2, varscan2
- IRAG1 | c.492G>T p.L164= | Silent (SNP) | VAF 144/317 reads (45%) | catalogued as COSV70211134; called by muse, mutect2, varscan2
- ISL2 | c.624C>G p.T208= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV51957913; called by muse, mutect2, varscan2
- IZUMO1 | c.126T>C p.P42= | Silent (SNP) | VAF 142/315 reads (45%) | catalogued as rs755793202, COSV59568376; called by muse, mutect2, varscan2
- KLK6 | c.495T>A p.R165= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV59565699; called by muse, mutect2, varscan2
- KLK8 | c.387G>A p.Q129= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs771272333, COSV51592082; called by muse, mutect2, varscan2
- N4BP2L2 | c.2274A>G p.K758= (on ENST00000674422; = p.K329= on NM_033111.4) | Silent (SNP) | VAF 160/303 reads (53%) | catalogued as COSV62633062; called by muse, mutect2, varscan2
- NECAB1 | c.735G>C p.G245= | Silent (SNP) | VAF 117/309 reads (38%) | catalogued as COSV70240130; called by muse, mutect2, varscan2
- NPC1L1 | c.135G>A p.L45= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs761127381, COSV56925497; called by muse, mutect2, varscan2
- PITPNM2 | c.339C>T p.T113= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as COSV54901166, COSV54903193; called by muse, mutect2, varscan2
- PMEPA1 | c.603G>A p.R201= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV55693721, COSV99671941; called by muse, mutect2, varscan2
- PRKG1 | c.1825C>T p.L609= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as rs541150590, COSV64770865, COSV64776061; called by muse, mutect2, varscan2
- RHPN1 | c.423C>T p.Y141= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs765617981, COSV56646881; called by muse, mutect2, varscan2
- SERTAD1 | c.438G>T p.G146= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV63596186; called by muse, mutect2, varscan2
- SPANXB1 | c.21C>A p.V7= | Silent (SNP) | VAF 252/1127 reads (22%) | called by muse, varscan2
- ST14 | c.351C>T p.A117= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV53833364; called by muse, mutect2, varscan2
- STARD3 | c.312C>T p.F104= | Silent (SNP) | VAF 231/385 reads (60%) | catalogued as COSV60420488; called by muse, mutect2, varscan2
- TLR7 | c.2130A>G p.Q710= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as COSV101027693; called by muse, mutect2, varscan2
- TMPRSS12 | c.222A>G p.Q74= | Silent (SNP) | VAF 58/123 reads (47%) | catalogued as COSV68256368; called by muse, mutect2, varscan2
- VWA8 | c.3072G>T p.G1024= | Silent (SNP) | VAF 111/286 reads (39%) | catalogued as COSV55697200; called by muse, mutect2, varscan2
- ZFP42 | c.609T>A p.A203= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV58817560; called by muse, mutect2, varscan2
- ZNF326 | c.1251A>G p.L417= | Silent (SNP) | VAF 225/506 reads (44%) | catalogued as COSV61035316; called by muse, mutect2
- ZNF510 | c.948A>G p.K316= | Silent (SNP) | VAF 106/206 reads (51%) | catalogued as COSV56297341; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1164A>C | Intron (SNP) | VAF 47/82 reads (57%) | catalogued as COSV63752090; called by muse, mutect2, varscan2
- DNAJC11 | c.*1148G>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99275390; called by muse, mutect2
- SUGT1P4-STRA6LP | n.1219C>T | RNA (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
